Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A4IQ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A4IQ-01A (Primary Tumor).

Gross Description: A mass is located in epidermis surface, with 5x4x1.5cm, firm, brown, black-gray surface

Microscopic Description: Epidermis is ulcerated and necrotic. Tumor is composed of sheets or groups of spindle or oval tumor cells with quite abundant cytoplasm. Sometime The cytoplasm contains finely divided melanin pigment granulaes. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are common.

Diagnosis Details: Malignant melanoma

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin, buttock

Tumor size: 5 x 4 x 1.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 1/9 positive for metastasis (Left axillary and pelvic lymph node 0/3, Left inguinal lymph node 1/6)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow depth: 15mm

Comments: Left buttock

ICD-0-3

Melanoma, NOS 8720/3

Site: skin, buttock C44.5

10/2/12

HRFA Discrepancy		X

Source: NCI Genomic Data Commons file 02257f1f-8e3e-4ccf-af02-170a548c6e65 (TCGA-EB-A4IQ.9EA1A9DE-540F-4DDA-BF6C-203342F47C7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).